Somatic mutation profile of tumor specimen SM-JU33C (aliquot 7316UP-1273) from CPTAC case C224967, project CPTAC-3 (Complex Epithelial Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenosquamous carcinoma.
Specimen SM-JU33C: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Cerebrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c39b5810-6b5b-4f05-b5e1-379899d6eb6f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 1105291 (Blood Derived Normal), aliquot 7316UP-743-1105291; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/95fb9b6c-3b81-4b24-9d5b-03fc2842e9f0

The open-access MAF lists 3 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1, Intron 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFASC | c.286T>C p.S96P (on ENST00000339876 / NM_001378329.1; = p.S90P on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/328 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); called by muse, mutect2
- FAAH2 | c.1308T>A p.R436= | Silent (SNP) | VAF 8/168 reads (5%) | called by muse, mutect2
- GALNT7 | c.966-177del | Intron (DEL) | VAF 4/26 reads (15%) | called by mutect2, pindel, varscan2
